Somatic mutation profile of tumor specimen C3N-02437-02 (aliquot CPT0159110006) from CPTAC case C3N-02437, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.4 years (22,411 days).
Specimen C3N-02437-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f66be4f-c01e-4c18-8d08-a58ad4254478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02437-31 (Blood Derived Normal), aliquot CPT0159380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/090ee566-6d89-4e14-9b92-903c008eff8b

The open-access MAF lists 417 somatic variants for this specimen: 280 protein-altering or splice-affecting, 91 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 91, Frame Shift Del 52, Intron 19, Nonsense Mutation 13, 3'UTR 12, Frame Shift Ins 10, RNA 8, 5'UTR 6, Splice Site 5, In Frame Del 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 60/403 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.167); catalogued as rs188859061, COSV66560684, COSV66576644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GREB1L | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1311814599; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 68/191 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 46/55 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 75/211 reads (36%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABRA | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs543076495; called by muse, mutect2
- ADGRF2 | c.1957G>A p.A653T (on ENST00000296862 / NM_001368115.2; = p.A585T on NM_153839.7) | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771938865, COSV57287952; called by muse, mutect2, varscan2
- AIM2 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV63701483; called by muse, mutect2
- ALPK3 | c.4240G>T p.G1414C | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV51940419; called by muse, mutect2, varscan2
- ANKRD17 | c.372C>G p.D124E | Missense Mutation (SNP) | VAF 108/326 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs748463495, COSV58225604; called by muse, mutect2, varscan2
- APLP1 | c.1645C>T p.R549* (on ENST00000221891 / NM_001024807.3; = p.R548* on NM_005166.4) | Nonsense Mutation (SNP) | VAF 71/242 reads (29%) | catalogued as rs776958157, COSV55701572, COSV55702466; called by muse, mutect2, varscan2
- ARHGAP22 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 13/371 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV50966335; called by muse, mutect2
- ARID1A | c.5124+1G>T p.X1708_splice | Splice Site (SNP) | VAF 53/137 reads (39%) | catalogued as COSV61378288, COSV61392093; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 76/198 reads (38%) | catalogued as COSV61389445; called by mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | catalogued as rs1558150870; called by mutect2, varscan2
- ATG16L1 | c.1774G>A p.V592I (on ENST00000392017 / NM_030803.7; = p.V573I on NM_017974.4) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs576438723; called by muse, mutect2, varscan2
- ATG2B | c.4718C>T p.P1573L | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs761449064; called by muse, varscan2
- ATP1B2 | c.708+1G>A p.X236_splice | Splice Site (SNP) | VAF 101/251 reads (40%) | catalogued as rs1466754424, COSV51515331; called by muse, mutect2, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs771612620; called by mutect2, pindel
- AZIN2 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs373343151, COSV53860765; called by muse, mutect2
- BMP8B | c.461T>G p.I154S | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs1447203533; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 34/89 reads (38%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPIFC | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs376981555; called by muse, mutect2, varscan2
- BSN | c.6662G>A p.R2221H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs149454072, COSV56530420; called by muse, mutect2
- BTK | c.557del p.K186Sfs*13 | Frame Shift Del (DEL) | VAF 67/477 reads (14%) | catalogued as CD951632, COSV58117651; called by mutect2, varscan2
- C10orf53 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1037837931; called by muse, mutect2, varscan2
- C1QL2 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1439684634; called by muse, mutect2
- C6orf89 | c.514G>A p.A172T (on ENST00000373685; = p.A179T on NM_152734.4) | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs771688537; called by muse, mutect2, varscan2
- CACNA1B | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1221419015; called by muse, mutect2, varscan2
- CAMK2B | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51659616; called by muse, mutect2, varscan2
- CDH1 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 211/552 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.124); catalogued as rs587781404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.1577del p.F526Sfs*3 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1209448007; called by mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs749463697; called by mutect2, pindel
- CEP43 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100835607; called by muse, mutect2
- CIT | c.5900G>A p.R1967H | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55866472; called by muse, mutect2
- CNTN2 | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 111/636 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs752953151; called by muse, mutect2, varscan2
- CPSF2 | c.1654del p.I552Sfs*5 | Frame Shift Del (DEL) | VAF 84/244 reads (34%) | catalogued as rs758712860; called by mutect2, pindel, varscan2
- CRNN | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.085); catalogued as rs201339909; called by muse, mutect2, varscan2
- CRYBG3 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542307607, COSV69195473; called by muse, mutect2, varscan2
- CTBP2 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 137/393 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs77603788, COSV58333675; called by muse, mutect2, varscan2
- CYP19A1 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs973140439; called by muse, mutect2, varscan2
- CYP26A1 | c.377_378del p.S126* | Frame Shift Del (DEL) | VAF 99/334 reads (30%) | catalogued as rs1486216310; called by pindel, varscan2
- CYP8B1 | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 24/509 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60226997; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs766714372; called by mutect2, varscan2
- DGKQ | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs374013481; called by muse, mutect2, varscan2
- DNAH10 | c.5522C>T p.P1841L (on ENST00000409039; = p.P1780L on NM_207437.3) | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs1232526501; called by muse, mutect2, varscan2
- DVL2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs146828816; called by muse, mutect2, varscan2
- EPB41L2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370238340; called by muse, mutect2
- EPHB3 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761663522; called by muse, mutect2, varscan2
- F5 | c.2721G>A p.W907* | Nonsense Mutation (SNP) | VAF 60/239 reads (25%) | catalogued as rs779021773; called by muse, mutect2, varscan2
- FAAP100 | c.1404-4G>A | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as rs376849624; called by mutect2, varscan2
- FAT3 | c.11389G>A p.D3797N | Missense Mutation (SNP) | VAF 139/354 reads (39%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.511); catalogued as rs771733194, COSV53132862, COSV53134863; called by muse, mutect2, varscan2
- FBN2 | c.3043C>T p.P1015S | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV52534337; called by muse, mutect2
- FCGBP | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146461520; called by muse, mutect2, varscan2
- FER1L5 | c.5596G>A p.D1866N (on ENST00000623019; = p.D1830N on NM_001293083.2) | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776912193, COSV53842669; called by muse, mutect2
- FOXS1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs772430610, COSV54067921; called by muse, mutect2
- GDF11 | c.136del p.E46Sfs*31 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs1412840296; called by mutect2, pindel, varscan2
- GRID1 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.018); catalogued as COSV100023246; called by muse, mutect2, varscan2
- H2BC17 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV58154150; called by muse, mutect2
- HPS6 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs201628418; called by muse, mutect2, varscan2
- ICE1 | c.3306G>T p.E1102D | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs780765389; called by muse, mutect2, varscan2
- ITPR3 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762303157, COSV65410134; called by muse, mutect2, varscan2
- KHSRP | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.579); catalogued as rs1329462088; called by muse, mutect2, varscan2
- KIAA1109 | c.9082C>T p.R3028C | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1173813709, COSV52678142; called by muse, mutect2, varscan2
- KIFC1 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100995993; called by muse, mutect2, varscan2
- KRTAP4-2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 141/418 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs754307555, COSV66658212; called by muse, mutect2, varscan2
- KRTAP5-8 | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 152/351 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); catalogued as COSV101273125; called by muse, mutect2, varscan2
- LEMD2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 101/287 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs752066713; called by muse, mutect2, varscan2
- LIN37 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs763621662; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 80/190 reads (42%) | catalogued as rs746202015; called by mutect2, varscan2
- MARCHF11 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 153/454 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV60137014; called by muse, mutect2, varscan2
- MCM3AP | c.1547T>C p.L516P | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52436628; called by muse, mutect2
- MCTP2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs143853824; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | catalogued as rs765803753; called by mutect2, varscan2
- MTCL1 | c.4961G>A p.R1654H (on ENST00000306329 / NM_001378206.1; = p.R1335H on NM_015210.4) | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768616569, COSV60404302; called by muse, mutect2, varscan2
- MYO1C | c.184G>A p.A62T (on ENST00000648651 / NM_001080779.2; = p.A27T on NM_033375.5) | Missense Mutation (SNP) | VAF 164/395 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs760702315, COSV63000251; called by muse, mutect2, varscan2
- NFATC2 | c.960dup p.K321Qfs*8 | Frame Shift Ins (INS) | VAF 46/137 reads (34%) | catalogued as rs781620004; called by mutect2, varscan2
- NINL | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs760971923; called by muse, mutect2, varscan2
- NOSIP | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV59200617; called by muse, mutect2, varscan2
- NOTCH3 | c.6102del p.G2035Vfs*50 | Frame Shift Del (DEL) | VAF 32/242 reads (13%) | catalogued as rs771517374; called by mutect2, pindel, varscan2
- NOXA1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs371771451; called by muse, mutect2, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as rs762677866, COSV100263457; called by pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 121/396 reads (31%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCDH8 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753481955, COSV58812766; called by muse, mutect2, varscan2
- PCDHA3 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 352/935 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as COSV63540988; called by muse, mutect2, varscan2
- PCDHA8 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 141/402 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV65329506; called by muse, mutect2, varscan2
- PCDHGB6 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 21/444 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV53946573; called by muse, mutect2
- PER2 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as rs1351750987, COSV54522055; called by muse, mutect2
- PHLPP2 | c.3050C>T p.A1017V | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); catalogued as rs374864964; called by muse, mutect2, varscan2
- PHYKPL | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs772375595, COSV100359488; called by muse, mutect2, varscan2
- PLXNA4 | c.5351C>T p.T1784M | Missense Mutation (SNP) | VAF 130/404 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372160247; called by muse, mutect2, varscan2
- PMFBP1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 76/245 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs552686844, COSV52828530; called by muse, mutect2, varscan2
- PNPLA7 | c.3622G>A p.G1208S | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs772857527; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 22/103 reads (21%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- PPAN-P2RY11 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 120/355 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs376033750; called by muse, mutect2, varscan2
- PPP2R1A | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59046217; called by muse, mutect2
- PRDX2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs145076374, COSV56879035; called by muse, mutect2
- RASSF7 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1412267353, COSV100272522; called by muse, mutect2
- RIC1 | c.3299G>A p.R1100Q | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs538140547, COSV99317387; called by muse, mutect2, varscan2
- RNF213 | c.11927G>A p.R3976H | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs766813218, COSV100299809, COSV100301593; called by muse, mutect2
- RYR3 | c.10423C>T p.H3475Y (on ENST00000389232; = p.H3476Y on NM_001036.6) | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV66804352; called by muse, mutect2, varscan2
- SCCPDH | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63618136; called by muse, mutect2, varscan2
- SDR42E1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs531784688, COSV100200774; called by muse, mutect2, varscan2
- SGTA | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 43/288 reads (15%) | catalogued as rs1263131894; called by muse, mutect2, varscan2
- SLC10A2 | c.953dup p.N318Kfs*21 | Frame Shift Ins (INS) | VAF 34/128 reads (27%) | catalogued as rs759302284; called by mutect2, pindel, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 86/236 reads (36%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC4A1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99293329; called by muse, mutect2, varscan2
- SLC4A2 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as rs772524567; called by muse, mutect2
- SLC6A15 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV57032000; called by muse, mutect2, varscan2
- SLITRK3 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1413834326, COSV104384557, COSV53848544, COSV99578223; called by muse, mutect2
- SMG9 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV54215437; called by muse, mutect2
- SPTBN5 | c.8335_8337del p.K2779del | In Frame Del (DEL) | VAF 66/164 reads (40%) | catalogued as rs1203170716; called by pindel, varscan2
- SRCAP | c.8152C>T p.R2718* | Nonsense Mutation (SNP) | VAF 93/270 reads (34%) | catalogued as COSV99351631; called by muse, mutect2, varscan2
- SSC5D | c.895+5G>A | Splice Region (SNP) | VAF 73/201 reads (36%) | catalogued as rs1199327063; called by muse, mutect2, varscan2
- SSTR1 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs1471239240, COSV99942926; called by muse, mutect2, varscan2
- TCF15 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 163/416 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs760281803; called by muse, mutect2, varscan2
- TJAP1 | c.902C>T p.P301L (on ENST00000372445 / NM_001146016.1; = p.P291L on NM_080604.3) | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs769267252; called by muse, mutect2, varscan2
- TMEM200C | c.1214C>A p.P405Q | Missense Mutation (SNP) | VAF 168/401 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs763306977; called by muse, mutect2, varscan2
- TMPRSS15 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.377); catalogued as COSV53051157; called by muse, mutect2, varscan2
- TNXB | c.9110C>G p.T3037S (on ENST00000647633; = p.T2790S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV64477256; called by muse, mutect2
- TRPM8 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs201855344, COSV61221365; called by muse, mutect2
- TSHR | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 29/474 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1305132938; called by muse, mutect2
- TTYH3 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs953373697; called by muse, mutect2, varscan2
- UCP3 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs145884716; called by muse, mutect2
- VSTM2L | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.737); catalogued as rs756269274; called by muse, mutect2, varscan2
- WDR81 | c.3509G>A p.G1170E (on ENST00000409644 / NM_001163809.2; = p.G119E on NM_152348.4) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs769235689, COSV100488802; called by muse, mutect2, varscan2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 57/156 reads (37%) | catalogued as rs747456682, COSV59688820; called by mutect2, pindel, varscan2
- ZFP37 | c.744dup p.H249Tfs*2 | Frame Shift Ins (INS) | VAF 8/63 reads (13%) | catalogued as rs1425115355; called by mutect2, pindel, varscan2
- ZNF131 | c.1639C>T p.R547W (on ENST00000509156 / NM_001330707.2; = p.R513W on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.727); catalogued as rs762694171; called by muse, mutect2, varscan2
- ZNF257 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs755947286, COSV71306204; called by mutect2, varscan2
- ZNF281 | c.275dup p.P93Sfs*34 | Frame Shift Ins (INS) | VAF 23/81 reads (28%) | catalogued as rs751889036; called by mutect2, varscan2
- ZNF425 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as rs1490375199; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- ABCC5 | c.2359G>T p.G787* | Nonsense Mutation (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- ACTN2 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 151/667 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM29 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ADAMTS12 | c.3869C>T p.A1290V | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); called by muse, mutect2
- AKAP9 | c.6117A>C p.E2039D (on ENST00000359028; = p.E2007D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2
- AMMECR1 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD9 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA11 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP2 | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 25/431 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.06); called by muse, mutect2
- ARID5B | c.1365del p.E456Kfs*23 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- AXL | c.1382C>T p.A461V (on ENST00000301178 / NM_021913.5; = p.A452V on NM_001699.6) | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.067); called by muse, mutect2
- B4GALT3 | c.638del p.G213Dfs*9 | Frame Shift Del (DEL) | VAF 51/272 reads (19%) | called by mutect2, pindel, varscan2
- BRD3 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 143/382 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACHD1 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.931); called by muse, mutect2
- CAPN7 | c.2369del p.L790Cfs*111 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- CCDC88A | c.1517del p.K506Rfs*22 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- CDIPT | c.197T>C p.M66T | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- CDK10 | c.485+2T>C p.X162_splice (on ENST00000353379 / NM_052988.5; = p.X91_splice on NM_052987.4) | Splice Site (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- CFDP1 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CHADL | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 100/265 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CIBAR2 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- COL16A1 | c.6G>T p.W2C | Missense Mutation (SNP) | VAF 27/401 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- COL6A3 | c.7837G>T p.G2613W | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- COPS7A | c.655del p.T219Pfs*21 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | called by mutect2, varscan2
- DENND4B | c.3728A>G p.D1243G | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DMBT1 | c.7604del p.P2535Hfs*24 (on ENST00000338354 / NM_001377530.1; = p.P1778Hfs*24 on NM_004406.3) | Frame Shift Del (DEL) | VAF 64/180 reads (36%) | called by mutect2, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- DNMT3B | c.596del p.G199Afs*27 | Frame Shift Del (DEL) | VAF 101/341 reads (30%) | called by mutect2, pindel, varscan2
- EML5 | c.4862del p.G1621Efs*19 (on ENST00000380664; = p.G1629Efs*19 on NM_183387.3) | Frame Shift Del (DEL) | VAF 64/184 reads (35%) | called by mutect2, pindel, varscan2
- ERC1 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ERP44 | c.421del p.S141Vfs*10 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- EXT1 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 104/313 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FAM135A | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- FAM13B | c.2420T>C p.V807A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT1 | c.7659dup p.L2554Tfs*2 | Frame Shift Ins (INS) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- FBXL13 | c.121del p.M41* | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- FCGRT | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 13/402 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2
- FLVCR1 | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GASK1A | c.1568T>C p.M523T | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- GATA6 | c.1657A>G p.T553A | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- GDF2 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- GHR | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 122/349 reads (35%) | called by muse, mutect2, varscan2
- GNB2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GRIN3A | c.3321_3323del p.R1108del | In Frame Del (DEL) | VAF 42/163 reads (26%) | called by mutect2, pindel, varscan2
- GRM4 | c.272A>T p.N91I | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- H6PD | c.1846C>A p.L616M | Missense Mutation (SNP) | VAF 192/591 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- HDLBP | c.2240del p.G747Afs*27 | Frame Shift Del (DEL) | VAF 115/593 reads (19%) | called by mutect2, pindel, varscan2
- HRH3 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 50/667 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.369); called by muse, mutect2
- ICAM2 | c.328+7G>A | Splice Region (SNP) | VAF 79/269 reads (29%) | called by muse, mutect2, varscan2
- IPO9 | c.1328_1328+3del p.X443_splice | Splice Site (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- IRGQ | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 63/171 reads (37%) | called by mutect2, varscan2
- KBTBD4 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 73/455 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KIAA1210 | c.1310dup p.L437Ffs*19 | Frame Shift Ins (INS) | VAF 52/122 reads (43%) | called by mutect2, pindel, varscan2
- KIF26B | c.2173G>T p.G725* | Nonsense Mutation (SNP) | VAF 80/412 reads (19%) | called by muse, mutect2, varscan2
- KRTAP25-1 | c.29del p.F10Sfs*27 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, varscan2
- LAMC2 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 83/457 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LINGO1 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LPL | c.615dup p.V206Cfs*26 | Frame Shift Ins (INS) | VAF 122/366 reads (33%) | called by mutect2, pindel, varscan2
- LRRC37A3 | c.550T>C p.Y184H | Missense Mutation (SNP) | VAF 33/685 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); called by muse, mutect2
- LRRIQ1 | c.3724A>G p.S1242G | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- MACF1 | c.17261_17262del p.T5754Rfs*8 (on ENST00000372915; = p.T3796Rfs*8 on NM_012090.5) | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | called by mutect2, pindel
- MAMDC4 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP2 | c.4250C>A p.A1417D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); called by muse, mutect2
- MCRS1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- MCTP2 | c.1547del p.L516* | Frame Shift Del (DEL) | VAF 11/109 reads (10%) | called by mutect2, pindel
- MEAF6 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MED13 | c.3958G>T p.G1320C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKRN3 | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2
- MRPS27 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- MYOF | c.3955T>C p.F1319L | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCOA3 | c.2164G>A p.V722I | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- NEK4 | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 131/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NKPD1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOS2 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 31/225 reads (14%) | called by muse, mutect2, varscan2
- NR1H4 | c.454C>A p.L152M (on ENST00000551379 / NM_001206993.2; = p.L142M on NM_005123.4) | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NT5C1B | c.1621G>A p.A541T (on ENST00000359846 / NM_001199086.2; = p.A481T on NM_033253.4) | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUAK2 | c.1597del p.L533Wfs*11 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- OBSCN | c.13764del p.E4590Rfs*92 | Frame Shift Del (DEL) | VAF 124/673 reads (18%) | called by mutect2, pindel, varscan2
- OR10H5 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4L1 | c.206del p.L69Wfs*13 | Frame Shift Del (DEL) | VAF 39/88 reads (44%) | called by mutect2, pindel, varscan2
- PCDHB13 | c.1094_1095del p.V365Gfs*10 | Frame Shift Del (DEL) | VAF 58/248 reads (23%) | called by pindel, varscan2
- PITPNM1 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PLXNA2 | c.1341del p.F447Lfs*9 | Frame Shift Del (DEL) | VAF 143/670 reads (21%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.3746G>A p.C1249Y | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PML | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- POLR1A | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- POLR1A | c.2468G>A p.G823E | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POM121L12 | c.139dup p.Q47Pfs*99 | Frame Shift Ins (INS) | VAF 66/277 reads (24%) | called by mutect2, pindel, varscan2
- PRG4 | c.1887del p.E630Rfs*282 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- PRH1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 224/1004 reads (22%) | called by muse, varscan2
- PRRT4 | c.2681G>A p.S894N | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTGER4 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- RAB6C | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- RASGEF1A | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RBM47 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RBMXL1 | c.721_723del p.Y241del | In Frame Del (DEL) | VAF 48/176 reads (27%) | called by pindel, varscan2
- RBMXL3 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELL2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, varscan2
- REPS2 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RETREG1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 177/482 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROS1 | c.5771C>T p.A1924V | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- RYR2 | c.9976C>A p.L3326I | Missense Mutation (SNP) | VAF 53/314 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- RYR3 | c.1256G>A p.S419N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SAE1 | c.1036A>G p.K346E | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SBF2 | c.2182A>T p.S728C | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SERPINA6 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- SESN3 | c.1123_1125del p.L375del | In Frame Del (DEL) | VAF 28/75 reads (37%) | called by pindel, varscan2
- SETD3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by mutect2, pindel
- SH2D2A | c.695_696del p.E232Gfs*50 | Frame Shift Del (DEL) | VAF 32/170 reads (19%) | called by pindel, varscan2
- SHOX | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 16/542 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2
- SHROOM4 | c.2593G>T p.G865C | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2
- SIGLEC10 | c.1160del p.P387Qfs*4 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- SIRT3 | c.77del p.G26Efs*21 | Frame Shift Del (DEL) | VAF 94/285 reads (33%) | called by mutect2, pindel, varscan2
- SLC17A1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLC26A8 | c.1820G>A p.C607Y | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.335); called by muse, mutect2
- SLC6A4 | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 36/574 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC7A10 | c.789-1G>T p.X263_splice | Splice Site (SNP) | VAF 16/340 reads (5%) | called by muse, mutect2
- SMCR8 | c.1790T>G p.L597R | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTAN1 | c.5192A>G p.D1731G | Missense Mutation (SNP) | VAF 96/724 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STT3B | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- STYXL2 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 139/609 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TAF1L | c.2623G>T p.G875W | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TECTA | c.5373del p.Y1792Mfs*13 | Frame Shift Del (DEL) | VAF 56/171 reads (33%) | called by mutect2, pindel, varscan2
- TMCC2 | c.496A>G p.S166G | Missense Mutation (SNP) | VAF 122/482 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM248 | c.58del p.L20Wfs*5 | Frame Shift Del (DEL) | VAF 58/167 reads (35%) | called by mutect2, pindel, varscan2
- TRADD | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 31/590 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- TRAV36DV7 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSGA13 | c.683G>T p.R228M | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- UNCX | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 96/352 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- USP9X | c.5477C>G p.P1826R | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, varscan2
- XK | c.775A>G p.S259G | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- YKT6 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZBED4 | c.1939A>G p.K647E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ZBP1 | c.98A>T p.Q33L | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.214); called by muse, mutect2
- ZBTB38 | c.2170del p.S724Hfs*3 | Frame Shift Del (DEL) | VAF 66/196 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB41 | c.447del p.F149Lfs*11 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- ZBTB7C | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ZDHHC5 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZFHX3 | c.3517C>T p.Q1173* | Nonsense Mutation (SNP) | VAF 80/211 reads (38%) | called by muse, mutect2, varscan2
- ZNF407 | c.5311A>G p.K1771E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ZP4 | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC011005.1 | c.495C>T p.P165= | Silent (SNP) | VAF 153/462 reads (33%) | catalogued as rs746997436, COSV71955994; called by muse, mutect2, varscan2
- ACAA1 | c.891C>T p.G297= | Silent (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- ADAM9 | c.1221G>A p.K407= | Silent (SNP) | VAF 75/216 reads (35%) | catalogued as rs748021542; called by muse, mutect2, varscan2
- ADARB2 | c.804C>T p.P268= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ANK1 | c.2817G>A p.P939= | Silent (SNP) | VAF 216/597 reads (36%) | catalogued as rs751319722, COSV55872519; called by muse, mutect2, varscan2
- ANKS3 | c.432C>T p.S144= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs757123927; called by muse, mutect2, varscan2
- ARHGAP39 | c.2331G>A p.V777= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- ASRGL1 | c.873C>T p.G291= | Silent (SNP) | VAF 77/530 reads (15%) | called by muse, mutect2, varscan2
- ATG2A | c.1185C>T p.S395= | Silent (SNP) | VAF 165/408 reads (40%) | catalogued as rs767173132, COSV101034170; called by muse, mutect2, varscan2
- BCL11B | c.1680G>A p.S560= (on ENST00000357195 / NM_001282237.2; = p.S489= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/401 reads (7%) | catalogued as rs369023141; called by muse, mutect2
- BRSK1 | c.996C>T p.R332= | Silent (SNP) | VAF 87/200 reads (44%) | catalogued as rs139469654; called by muse, mutect2, varscan2
- C2orf78 | c.258C>T p.G86= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV101280979; called by muse, mutect2
- CACNA1B | c.3027G>A p.V1009= | Silent (SNP) | VAF 217/578 reads (38%) | catalogued as rs1287095565; called by muse, mutect2, varscan2
- CBARP | c.2100G>A p.P700= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- CLASRP | c.321C>T p.D107= | Silent (SNP) | VAF 26/298 reads (9%) | catalogued as rs771947338, COSV99674320; called by muse, mutect2
- COL27A1 | c.2085G>A p.L695= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- CTLA4 | c.435C>T p.N145= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs777300741; called by muse, mutect2, varscan2
- CYLD | c.2676C>T p.A892= | Silent (SNP) | VAF 192/558 reads (34%) | catalogued as rs1289366169, COSV61093166, COSV61097597; called by muse, mutect2, varscan2
- DCAF12L1 | c.372C>T p.D124= | Silent (SNP) | VAF 11/200 reads (6%) | catalogued as COSV64422842; called by muse, mutect2
- DCAF5 | c.84G>A p.L28= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- DDX54 | c.2349C>T p.D783= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV58374644; called by muse, mutect2, varscan2
- DGKQ | c.2187C>T p.N729= | Silent (SNP) | VAF 82/199 reads (41%) | catalogued as rs768175623; called by muse, mutect2, varscan2
- DNAH17 | c.12558G>A p.G4186= | Silent (SNP) | VAF 204/529 reads (39%) | catalogued as rs761393901; called by muse, mutect2, varscan2
- DPP6 | c.87C>T p.G29= | Silent (SNP) | VAF 132/348 reads (38%) | called by muse, mutect2, varscan2
- DST | c.19476C>T p.H6492= (on ENST00000361203 / NM_001374722.1; = p.H4189= on NM_015548.5) | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- DYRK2 | c.1317C>T p.G439= (on ENST00000344096 / NM_006482.3; = p.G366= on NM_003583.4) | Silent (SNP) | VAF 87/251 reads (35%) | called by muse, mutect2, varscan2
- ENGASE | c.1914G>A p.G638= | Silent (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- ENPP6 | c.546C>A p.A182= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- EPM2A | c.231G>A p.E77= | Silent (SNP) | VAF 217/525 reads (41%) | called by muse, mutect2, varscan2
- FETUB | c.84C>A p.P28= | Silent (SNP) | VAF 18/533 reads (3%) | called by muse, mutect2
- FGF18 | c.531C>T p.R177= | Silent (SNP) | VAF 18/463 reads (4%) | called by muse, mutect2
- FNIP1 | c.1014G>A p.L338= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- HDAC7 | c.1993C>A p.R665= (on ENST00000427332; = p.R704= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as COSV50345329; called by muse, mutect2, varscan2
- HECTD3 | c.100C>A p.R34= | Silent (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- HHIPL2 | c.372G>A p.T124= | Silent (SNP) | VAF 11/304 reads (4%) | catalogued as COSV58566633; called by muse, mutect2
- HMCN2 | c.846C>T p.V282= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as rs782627150; called by muse, mutect2, varscan2
- HSPH1 | c.630G>A p.V210= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1453018625; called by muse, mutect2
- IL1B | c.243C>T p.C81= | Silent (SNP) | VAF 17/607 reads (3%) | called by muse, mutect2
- KALRN | c.4848C>T p.D1616= | Silent (SNP) | VAF 75/193 reads (39%) | catalogued as rs756857913; called by muse, mutect2, varscan2
- KDM2B | c.1665C>T p.H555= | Silent (SNP) | VAF 67/171 reads (39%) | catalogued as rs782222166; called by muse, mutect2, varscan2
- KIAA1210 | c.2550C>T p.F850= | Silent (SNP) | VAF 63/168 reads (38%) | called by muse, mutect2, varscan2
- KIAA1614 | c.1806C>T p.T602= | Silent (SNP) | VAF 27/303 reads (9%) | catalogued as rs752934576, COSV62550412; called by muse, mutect2
- KIF12 | c.114C>A p.A38= | Silent (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- KIRREL1 | c.1200G>A p.V400= | Silent (SNP) | VAF 103/553 reads (19%) | called by muse, mutect2, varscan2
- KLF12 | c.1062C>T p.C354= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as COSV66573714; called by muse, mutect2, varscan2
- KRTAP13-1 | c.156C>A p.L52= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- L1CAM | c.2709G>A p.S903= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as rs146224667; called by muse, mutect2, varscan2
- LHX1 | c.444G>A p.P148= | Silent (SNP) | VAF 207/530 reads (39%) | catalogued as rs754162995; called by muse, mutect2, varscan2
- MINK1 | c.2625C>T p.T875= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs575342987; called by muse, mutect2, varscan2
- MYBPH | c.732C>T p.Y244= | Silent (SNP) | VAF 75/327 reads (23%) | catalogued as rs759565348; called by muse, mutect2, varscan2
- NOTUM | c.1308G>A p.L436= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as rs1211587032, COSV101293791; called by muse, mutect2
- NUTM1 | c.414T>C p.N138= | Silent (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- OBSCN | c.15007C>T p.L5003= | Silent (SNP) | VAF 75/498 reads (15%) | called by muse, mutect2, varscan2
- OCM | c.321G>A p.V107= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- PCDH19 | c.1239C>T p.R413= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as rs1569314929; called by muse, mutect2, varscan2
- PCDHAC2 | c.1341G>A p.P447= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as rs200195064; called by muse, mutect2, varscan2
- PCDHB2 | c.1650C>T p.R550= | Silent (SNP) | VAF 249/865 reads (29%) | catalogued as COSV50573702; called by muse, varscan2
- PCDHB7 | c.972C>T p.G324= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs754071135, COSV50807468; called by muse, mutect2, varscan2
- PCDHGA4 | c.819C>T p.F273= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as rs1394652053; called by muse, mutect2
- PGGT1B | c.384C>T p.G128= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs769443608; called by muse, mutect2, varscan2
- PLEKHH3 | c.1608C>T p.R536= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- POLD1 | c.2835G>A p.V945= | Silent (SNP) | VAF 87/267 reads (33%) | called by muse, mutect2, varscan2
- PRRC2C | c.8319T>C p.P2773= (on ENST00000367742; = p.P2771= on NM_015172.4) | Silent (SNP) | VAF 26/720 reads (4%) | called by muse, mutect2
- PSEN1 | c.792G>A p.P264= | Silent (SNP) | VAF 49/181 reads (27%) | catalogued as rs150301281; called by muse, mutect2, varscan2
- RABGAP1L | c.1020C>T p.N340= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1265572545; called by muse, mutect2
- RGPD4 | c.3738A>G p.T1246= | Silent (SNP) | VAF 168/517 reads (32%) | catalogued as COSV61747369; called by muse, mutect2, varscan2
- RIT2 | c.36C>A p.G12= | Silent (SNP) | VAF 50/158 reads (32%) | called by muse, mutect2, varscan2
- RMDN1 | c.396C>T p.S132= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV52208142; called by muse, mutect2
- SDK2 | c.762C>T p.D254= | Silent (SNP) | VAF 73/157 reads (46%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.972C>T p.N324= | Silent (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- SESN1 | c.198G>A p.Q66= (on ENST00000356644 / NM_001199933.1; = p.Q125= on NM_014454.3) | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- SLC22A6 | c.1404C>T p.G468= | Silent (SNP) | VAF 106/281 reads (38%) | called by mutect2, varscan2
- SORBS1 | c.3465C>T p.D1155= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs533197181; called by muse, mutect2, varscan2
- SPATA31D1 | c.1350C>A p.S450= | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- STARD9 | c.6927G>A p.R2309= | Silent (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- TEX14 | c.1296A>G p.A432= (on ENST00000240361 / NM_001201457.2; = p.A426= on NM_031272.5) | Silent (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- TRANK1 | c.1086G>A p.L362= | Silent (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2
- TRAPPC8 | c.69G>A p.L23= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs1409352787; called by muse, mutect2, varscan2
- TRPC4 | c.927G>A p.L309= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs749813796, COSV59009108; called by muse, mutect2, varscan2
- TRPV1 | c.441C>T p.N147= | Silent (SNP) | VAF 69/190 reads (36%) | catalogued as rs200647940; called by muse, mutect2, varscan2
- TTYH1 | c.123G>A p.Q41= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- TTYH3 | c.1314C>A p.L438= | Silent (SNP) | VAF 76/201 reads (38%) | called by muse, mutect2, varscan2
- WDR24 | c.1659C>T p.G553= (on ENST00000248142; = p.G423= on NM_032259.4) | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- ZCCHC9 | c.798T>C p.P266= | Silent (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- ZNF230 | c.315G>A p.Q105= | Silent (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- ZNF264 | c.963C>T p.G321= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, mutect2, varscan2
- ZNF428 | c.267G>A p.P89= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs774541546; called by muse, mutect2
- ZNF483 | c.1860G>A p.T620= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs142830150; called by muse, mutect2, varscan2
- ZNF485 | c.1131T>C p.T377= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- ZNF638 | c.5115A>G p.L1705= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV52495069; called by muse, mutect2
- ZNF875 | c.1461C>T p.H487= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs749379348; called by muse, mutect2
- ANKRD20A5P | n.385A>G | RNA (SNP) | VAF 31/493 reads (6%) | called by muse, mutect2
- ANKRD20A8P | n.508del | RNA (DEL) | VAF 8/14 reads (57%) | catalogued as rs782135999; called by mutect2, varscan2
- ARHGEF9 | c.*6A>G | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- BAHCC1 | c.-167C>T | 5'UTR (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- BSG | c.416-316A>C | Intron (SNP) | VAF 13/285 reads (5%) | called by muse, mutect2
- CAMK2G | c.1444+118C>T | Intron (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- CHRNE | c.1327-45G>A | Intron (SNP) | VAF 216/537 reads (40%) | called by muse, mutect2, varscan2
- COASY | c.915+51C>T | Intron (SNP) | VAF 46/112 reads (41%) | catalogued as rs545304443; called by muse, mutect2, varscan2
- CYBA | c.203+31G>A | Intron (SNP) | VAF 82/238 reads (34%) | catalogued as rs755503223; called by muse, mutect2
- DCAF17 | c.*188del | 3'UTR (DEL) | VAF 26/65 reads (40%) | catalogued as rs746203651; called by mutect2, varscan2
- DHRS4 | c.722+196A>G | Intron (SNP) | VAF 35/158 reads (22%) | catalogued as rs1322352758; called by muse, mutect2, varscan2
- EFEMP2 | c.-33G>T | 5'UTR (SNP) | VAF 71/237 reads (30%) | catalogued as rs1412416670; called by muse, mutect2, varscan2
- FAM205BP | n.1978C>T | RNA (SNP) | VAF 36/827 reads (4%) | catalogued as rs1413617037; called by muse, mutect2
- FAM20A | c.*2077C>T | 3'UTR (SNP) | VAF 105/290 reads (36%) | called by muse, mutect2, varscan2
- FANCM | c.5341-649T>A | Intron (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- FRMPD2B | n.1122A>G | RNA (SNP) | VAF 38/92 reads (41%) | called by mutect2, varscan2
- GP1BB | chr22:19723405 G>A | 5'Flank (SNP) | VAF 65/442 reads (15%) | called by muse, mutect2, varscan2
- HAPLN4 | c.-34G>A | 5'UTR (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- HOXA10 | c.*906dup | 3'UTR (INS) | VAF 30/75 reads (40%) | called by mutect2, varscan2
- HSPA12A | c.-18G>A | 5'UTR (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- IL2RG | c.454+39G>A | Intron (SNP) | VAF 71/197 reads (36%) | called by muse, mutect2, varscan2
- INTS1 | c.*21del | 3'UTR (DEL) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- JPH3 | c.2167-511del | Intron (DEL) | VAF 64/188 reads (34%) | catalogued as rs767270778; called by mutect2, varscan2
- KRT5 | c.*8C>T | 3'UTR (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- LGALS8 | c.550-117del | Intron (DEL) | VAF 59/301 reads (20%) | called by mutect2, pindel, varscan2
- LINC00692 | n.663T>C | RNA (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- METTL26 | c.567+11del | Intron (DEL) | VAF 56/151 reads (37%) | called by mutect2, pindel, varscan2
- MIR124-3 | n.7C>T | RNA (SNP) | VAF 16/200 reads (8%) | catalogued as rs1449178178; called by muse, mutect2
- NFYB | c.7-3223G>A | Intron (SNP) | VAF 12/130 reads (9%) | catalogued as rs1337530425; called by muse, mutect2
- NOTCH1 | c.5167+99G>A | Intron (SNP) | VAF 52/488 reads (11%) | catalogued as rs759009887; called by muse, mutect2, varscan2
- NWD1 | c.496+9G>A | Intron (SNP) | VAF 53/393 reads (13%) | catalogued as rs940518577, COSV100341749; called by muse, mutect2, varscan2
- OR7D1P | n.872G>A | RNA (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- PEX19 | c.*2414G>T | 3'UTR (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- PPP2R2B | c.-37C>T | 5'UTR (SNP) | VAF 144/367 reads (39%) | catalogued as rs1431033394; called by muse, varscan2
- PROX2 | c.*977G>C | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- ROR2 | c.494+37T>C | Intron (SNP) | VAF 83/176 reads (47%) | called by muse, mutect2, varscan2
- SDK1 | c.*3356C>T | 3'UTR (SNP) | VAF 26/177 reads (15%) | catalogued as rs373299996; called by muse, mutect2, varscan2
- SGSM2 | c.1653+115G>A | Intron (SNP) | VAF 15/73 reads (21%) | catalogued as rs1475782602, COSV52160603; called by muse, mutect2, varscan2
- SLC25A22 | c.203-11del | Intron (DEL) | VAF 39/214 reads (18%) | called by pindel, varscan2
- SNORD115-14 | n.71C>T | RNA (SNP) | VAF 78/243 reads (32%) | catalogued as rs375960026; called by muse, mutect2, varscan2
- TAOK2 | c.*377dup | 3'UTR (INS) | VAF 25/77 reads (32%) | called by mutect2, varscan2
- TMEM120A | c.564-32_564-30dup | Intron (INS) | VAF 44/131 reads (34%) | called by mutect2, pindel, varscan2
- TPTE2P5 | n.123-4345C>A | Intron (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- TSPAN15 | c.*541del | 3'UTR (DEL) | VAF 9/103 reads (9%) | catalogued as rs1026780474; called by mutect2, pindel
- VANGL2 | c.-45del | 5'UTR (DEL) | VAF 83/438 reads (19%) | called by mutect2, pindel, varscan2
- XIAP | c.*1549del | 3'UTR (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
